TCGA case TCGA-09-0364 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6746533a-8d0b-4ebc-87ec-49c8738121a8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Dead; Days to death: 887 days (2.4 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 80.1 years (29,262 days); Year of diagnosis: 1998; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: 11-20 mm; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 188 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 188 days; Number of cycles: 6; Treatment dose: 125 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 502 days (1.4 years); Days to treatment end: 538 days (1.5 years); Treatment dose: 4,400 cGy; Treatment anatomic sites: Locoregional Site.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 81.2 years (29,657 days); Days to diagnosis: 395 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (2 entries)
- Day 395 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 395 days (1.1 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 887 days (2.4 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-09-0364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-09-0364-01A-01-BS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-09-0364-01A-02-BS2: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-09-0364-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Right; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Carboplatinum.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: taxol.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 887 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 887 days; disease-free interval: event (new tumor event after initially disease-free), 395 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 395 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-09-0364-01A-02D-0356-01): tumor purity 0.89, ploidy 3.16, whole-genome doublings 1.
